Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JP, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JP-06A (Metastatic).

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

Patient ID – Sample ID

(A) RIGHT AXILLARY LYMPH NODE LEVEL I, II AND III, EXCISION:

MELANOMA, METASTATIC TO SIX OF TWENTY-SEVEN LYMPH NODES (6/27).

Largest tumor deposit size: 30.0 x 16.0 mm (as per gross description)

Location: Subcapsular and intraparenchymal

Extracapsular extension: Present

Foreign material consistent with tattoo pigment.

Skin and subcutis with features consistent with previous biopsy site changes.

Diagnostic Discrepancy		☒

COMMENT

Lymph nodes marked with a stitch representing highest level III are negative for melanoma (0/3).

1 CD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary
C77.3
h 7/24/11

GROSS DESCRIPTION

(A) RIGHT AXILLARY LYMPH NODE LEVEL I, II AND III - A white-tan skin with incision scar (3.3 x 0.6 cm) and underlying fibroadipose tissue (6.5 x 3.0 x 8.5 cm) with a stitch marking highest level III lymph node. A surgical cavity (2.5 x 2.0 x 2.0 cm) is identified. Also multiple lymph nodes are identified ranging from 0.2 x 0.1 x 0.1 cm to 3.0 x 1.6 x 1.6 cm.

SECTION CODE: A1, skin; A2, A3, surgical cavity; A4-A8, each containing four lymph nodes; A9, two lymph nodes; A10-A12, each containing one lymph node, serially sectioned; A13-A15, each containing representative section of one lymph node, each cassette; A16, A17, A18, each containing one lymph node from highest associated to stitch.

CLINICAL HISTORY

Melanoma, right axillary

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file 344dd8a7-5c21-4683-894e-a80ea97b349e (TCGA-D3-A2JP.F23E963F-A9CF-4241-882E-385254FA5E97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).